Surgical pathology report (de-identified scan), TCGA case TCGA-36-2534, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2534-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

TCGA-36-2534

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

- 1) Omentectomy specimen: Multiple nodules of high grade serous carcinoma, consistent with ovarian origin.
- 2) Right salpingo-oophorectomy specimen: Serous adenocarcinoma, grade 3 out of 3, involving ovary and fallopian tube.
- 3) Pelvic fluid (see separate report) positive for malignant cells.

Clinical History as Provided by Submitting Physician:

Ref with bilateral pelvic masses. CT: Omental cake, peritoneal implants.

A. Omentum

[page 2 of 2]
B. R fallopian and query R ovary

Specimens Received:

A: omentum

B: right fallopian + query right ovary

Gross Description:

Specimen is submitted in two containers, each assigned by patient's name.

Container A, omentum. Specimen consists of an apron of great omentum measuring 25 X 15 X 4 cm, weighing 610 g. The omentum shows a firm nodule measuring 14 X 13 X 4 cm. Cross section of the nodule shows a tan-white fibrous structure with punctate hemorrhage and necrosis. Cross section of the remainder of the omentum shows six more nodules, ranging in size from 0.7 up to 4 cm in the greatest dimension. Representative sections submitted, A1-A2.

Container B, right fallopian tube with query right ovary. Specimen consists of a fallopian tube measuring 7 cm in length, 0.7 cm in diameter at the fimbria end, 2 cm in diameter at the proximal end. The fimbria end shows numerous firm nodules ranging in size from 0.3 up to 1.2 cm in diameter. That proximal end is embedded into the tumor mass measuring 5.5 X 4 X 2 cm. In the same container, a fragment of tumor mass is submitted, measuring 4 cm X 2.5 X 1.2 cm. Cross section of the proximal end of the fallopian tube shows a white nodule with focal hemorrhage and necrosis.

Sections are submitted as follows:

B1-B2 -proximal end of the fallopian tube

B3 -central portion of the fallopian tube

B4 -fimbria

B5-B6 -fragments of ovary

Source: NCI Genomic Data Commons file d23965b7-a340-47a7-b413-aade7d842db9 (TCGA-36-2534.B62A4922-AD09-4422-8CB2-BEA80A0FE533.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).